Surgical pathology report (de-identified scan), TCGA case TCGA-55-6969, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6969-01A (Primary Tumor).

[page 1 of 4]
Patient Results Report

Patient Name: [REDACTED]

MR #: [REDACTED]

Age: [REDACTED]

Sex: M

Collect [REDACTED] - PATHOLOGY RESULTS (LABORATORY) - Final
(Reported [REDACTED])

Results:

REPORT :

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Accession: [REDACTED]

Med. Rec: [REDACTED]

Billing Type: Inpatient

Location:

Service: Surgery

Gender: M

Taken [REDACTED]

Received [REDACTED]

Reported: [REDACTED]

Specimen(s) Received

A: A P window lymph nodes

B: Posterior hilar lymph node

C: Inter lobar

D: Hilar node

E: Left upper lobe bronchial margin

Pathologic Diagnosis

"A" - Lymph nodes, AP window, excision: No evidence of malignancy in six lymph nodes (0/6).

[page 2 of 4]
[REDACTED]

Patient Results Report

Patient Name: [REDACTED]

MR #: [REDACTED]

Age: [REDACTED]

Sex: M

"B" - Lymph nodes, posterior hilar, excision: no evidence of malignancy in one lymph node (0/1).

"C" - Lymph node, intralobar, excision: No evidence of malignancy in one lymph node (0/1).

"D" - Lymph node, hilar, excision: No evidence of malignancy in two lymph nodes (0/2).

"E" - Lung, left upper lobe, excision:

- Poorly differentiated adenocarcinoma.
- Tumor size: 3.5 cm.
- All surgical resection margins are clear (tumor does not involve the pleura and is 1.2 cm from the bronchial resection margin).
- No evidence of malignancy in three peribronchial lymph nodes (0/3).
- No evidence of lymphovascular space invasion.
- Adjacent lung tissue with emphysematous changes.

[REDACTED]

[REDACTED]

[REDACTED]

Clinical History

Left upper lobe cancer.

Intraoperative Consultation

[REDACTED]

[page 3 of 4]
Patient Results Report

Patient Name: [REDACTED]

MR #: [REDACTED]

Age: [REDACTED]

Sex: M

"E" - Left upper lobe: Bronchial margin negative for malignancy (microscopic frozen section).

Gross Description

"A" - Received in formalin labeled "AP window lymph nodes" consists of a 3.8 x 3 x 1 cm aggregate of fibroadipose tissue, which is bisected for potential lymph nodes. "A1" - five intact lymph nodes. A 3 x 1.5 x 0.8 cm lymph node is serially sectioned and entirely submitted as "A2-3."

"B" - Received in formalin labeled "posterior hilar gland lymph node" consists of a 2.8 x 1.8 x 0.8 cm lymph node, which is sectioned and entirely submitted as "B1."

"C" - Received in formalin labeled "intralobar" consists of a 2.8 x 1.3 x 0.7 cm lymph node, which is serially sectioned and entirely submitted as "C1."

"D" - Received in formalin labeled "hilar" consists of two lymph nodes, 0.8 x 0.7 x 0.4 and 2.2 x 0.7 x 0.5 cm. The lymph nodes are differentially inked blue and green, bisected, and entirely submitted as "D1."

"E" - Received fresh for frozen section labeled "left upper lobe" consists of a 313 gram (post resection weight), 17 x 11 x 6 cm lobe of lung. The pleura is purple-tan with a small amount of anthracotic pigmentation and an area of pleural retraction in the superior aspect of the specimen. This area of pleural retraction

[page 4 of 4]
[REDACTED]

Patient Results Report

Patient Name: [REDACTED]

MR #: [REDACTED]

Age: [REDACTED]

Sex: M

is inked green. The bronchial margin is removed and frozen en face as "FS-E1," remnant entirely submitted as "E1." Sectioning demonstrates a 3.5 x 3.5 x 2.0 cm firm white to gray ill-defined mass with scalloped borders clearly in the area of pleural retraction. This mass grossly comes to within 1.2 cm of the bronchial margin. Sections of the remaining specimen demonstrates soft red-brown crepitant parenchyma with distal dilated air spaces, which are present throughout but are most marked in the superoposterior aspect of the lung. There are no additional masses identified grossly. "E1" - bronchial margin (frozen section remnant), "E2" - lobar lymph nodes and vascular margin, en face, "E3-4" - mass with extension towards bronchial margin, "E5" - mass with relationship to overlying pleura, "E6" - mass with relationship to adjacent parenchyma, "E7" - parenchyma with dilated air spaces, and "E8" - grossly unremarkable parenchyma.

[REDACTED]

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Notes:

[REDACTED]

Source: NCI Genomic Data Commons file 819c1b04-8987-4971-8df2-238b693077bb (TCGA-55-6969.96B7D4C4-6513-4249-A6D5-B5CF0BF49AB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).